Gene-level copy-number profile of tumor specimen TCGA-N7-A4Y5-01A from TCGA case TCGA-N7-A4Y5, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Age at diagnosis: 87.8 years (32,058 days).
Specimen TCGA-N7-A4Y5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.64df4163-1a5d-4ddb-a42a-5f4e262df1b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N7-A4Y5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/adb2e030-7b4e-49a5-a73e-e61c35353a8c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,528; copy number 2: 29,448; copy number 3: 20,939; copy number 4: 4,391; copy number 5: 2,923; copy number 6: 448; copy number 7: 45; copy number 9: 57; copy number 10: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N7-A4Y5-01A-12D-A28Q-01): tumor purity 0.93, ploidy 2.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,506 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:96,566,357–123,028,605, 408 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr8:20,934,435–21,309,486, 10 genes, copy number 5: TMEM97P2, AC015468.3, AC021613.1, AC015468.1, AC015468.2, LINC02153, AC103719.1, AC021613.2, AC021613.3, AC021355.1.
- chr8:38,030,534–43,674,591, 145 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr8:46,810,696–145,066,685, 1,527 genes, copy number 5–9 (broad region; genes not listed).
- chr13:93,226,807–94,408,020, 1 gene, copy number 5 (within-gene range 3–5): GPC6.
- chr13:93,818,424–95,579,759, 22 genes, copy number 5: GPC6-AS2, RNA5SP35, GPC6-AS1, DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1.
- chr16:34,962,970–35,912,516, 81 genes, copy number 6 (broad region; genes not listed).
- chr18:20,946,906–22,419,294, 40 genes, copy number 5: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1.
- chr19:27,638,483–41,555,462, 547 genes, copy number 5–6 (broad region; genes not listed).
- chr19:41,551,568–41,552,274, 1 gene, copy number 5: AC243960.10.
- chr19:44,094,339–44,401,608, 14 genes, copy number 9 (within-gene range 4–9): ZNF224, AC021092.1, ZNF225, ZNF234, AC138470.2, ZNF226, ZNF227, ZNF235, AC138470.1, ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1.

Autosomal genes at a single copy (total copy number 1): 248. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
